Somatic mutation profile of tumor specimen TCGA-BR-A453-01A (aliquot TCGA-BR-A453-01A-11D-A24D-08) from TCGA case TCGA-BR-A453, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 52.0 years (18,988 days).
Specimen TCGA-BR-A453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38469a61-4977-47cc-ab1c-113d728d3852.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A453-10A (Blood Derived Normal), aliquot TCGA-BR-A453-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be075a5a-1805-4dee-89e3-2051a0d29cf1

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 3, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555515925, COSV55728800, COSV55733458; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS10 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV54359603, COSV99547505; called by muse, mutect2
- ARID1A | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 20/312 reads (6%) | catalogued as COSV61373074, COSV61387510; called by muse, mutect2
- CFAP58 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV63835987; called by muse, mutect2, varscan2
- ERG28 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV53164250; called by muse, mutect2
- FGF5 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56891706; called by muse, mutect2
- FUT7 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.703); catalogued as COSV99688549; called by muse, mutect2
- GPR158 | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs879170613, COSV66280670; called by muse, mutect2
- HCN4 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56084986; called by muse, mutect2
- IL1RL1 | c.62-1G>A p.X21_splice | Splice Site (SNP) | VAF 4/63 reads (6%) | catalogued as COSV99294250, COSV99294597; called by muse, mutect2
- KCNMB3 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.342); catalogued as COSV55984449; called by muse, mutect2
- KRT76 | c.610C>A p.L204M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60121766; called by muse, mutect2
- KRTAP26-1 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 11/214 reads (5%) | catalogued as COSV62128621, COSV62129252; called by muse, mutect2
- LARGE2 | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57659220; called by muse, mutect2
- LRCH3 | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV58396086; called by muse, mutect2
- MIP | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs966166555, COSV57509765; called by muse, mutect2
- MPIG6B | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV65390263; called by muse, mutect2
- MYO7B | c.3385C>T p.R1129W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758719218, COSV67345465, COSV67348795; called by muse, mutect2
- OR2A5 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV68739064; called by muse, mutect2, varscan2
- PCDHA7 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as rs782425324, COSV65342157, COSV65347667; called by muse, mutect2
- PCDHB10 | c.61T>G p.W21G | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs200335754, COSV53375539; called by muse, mutect2, varscan2
- PTPRB | c.3479A>T p.E1160V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV54251522; called by muse, mutect2, varscan2
- PTPRC | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as COSV61419803; called by muse, mutect2, varscan2
- PUM2 | c.2576T>C p.V859A | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV57584747; called by muse, mutect2
- SATB1 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58670439; called by muse, mutect2, varscan2
- SBF1 | c.2130G>A p.E710= | Splice Region (SNP) | VAF 5/89 reads (6%) | catalogued as COSV62370167; called by muse, mutect2
- SHE | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.702); catalogued as rs1425138721, COSV59072983; called by muse, mutect2
- SLC12A4 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV57925969, COSV57934752; called by muse, mutect2
- SNCAIP | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1476886099, COSV54420014; called by muse, mutect2
- UGT1A1 | c.341A>T p.K114M | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV59396863; called by muse, mutect2
- USP24 | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV53776984; called by muse, mutect2, varscan2
- USP42 | c.1621C>A p.L541I | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV60363951; called by muse, mutect2
- WAPL | c.2711G>A p.S904N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV99556662; called by muse, mutect2
- WDR17 | c.2495T>A p.I832N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54582198; called by muse, mutect2
- ZBTB22 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs1254306965, COSV56472277; called by muse, mutect2
- ZNF629 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1373669036; called by muse, mutect2
- ARFGAP3 | c.1518C>T p.V506= | Silent (SNP) | VAF 19/259 reads (7%) | catalogued as rs762282981, COSV54310590; called by muse, mutect2
- CA9 | c.1029T>C p.T343= | Silent (SNP) | VAF 7/154 reads (5%) | catalogued as COSV61407577; called by muse, mutect2
- COL28A1 | c.1515G>A p.E505= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs778601651, COSV68083214; called by muse, mutect2, varscan2
- CTDP1 | c.465C>T p.S155= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs767097152, COSV99310699; called by mutect2, varscan2
- DLC1 | c.520C>T p.L174= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as COSV52324891; called by muse, mutect2
- ODF4 | c.195G>A p.P65= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs144163492; called by muse, mutect2, varscan2
- PIK3R6 | c.2220G>A p.K740= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV61005442; called by muse, mutect2
- UTP25 | c.615T>A p.A205= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV71966138; called by muse, mutect2
- WDR47 | c.1527C>A p.G509= (on ENST00000369962 / NM_001142551.2; = p.G510= on NM_014969.5) | Silent (SNP) | VAF 12/244 reads (5%) | catalogued as COSV63059549; called by muse, mutect2
- ZNF44 | c.801C>T p.H267= (on ENST00000356109 / NM_001164276.2; = p.H219= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV61136190; called by muse, mutect2
- ZNF467 | c.1644C>T p.C548= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1437233026, COSV57373389; called by muse, mutect2, varscan2
